Gene-level copy-number profile of tumor specimen TCGA-DA-A1I5-06A from TCGA case TCGA-DA-A1I5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 32.7 years (11,928 days).
Specimen TCGA-DA-A1I5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.73ca3e70-5335-45fd-9795-96a6462e5523.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DA-A1I5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2c184f13-f086-4772-9622-4a0561618af5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 105; copy number 1: 25,300; copy number 2: 28,004; copy number 3: 6,201; copy number 4: 121; copy number 6: 83.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DA-A1I5-06A-11D-A191-01): tumor purity 0.56, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 105 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:10,532,145–10,632,203, 3 genes: AL135790.2, PTPRD-AS2, AL135790.1.
- chr9:12,685,439–13,836,571, 14 genes (within-gene range 0–1): TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1.
- chr9:16,203,935–16,870,843, 6 genes: C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–30,800,746, 80 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 83 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:67,225,464–73,624,941, 81 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:84,958,989–86,074,429, 2 genes, copy number 6 (within-gene range 2–6): CADM2, MIR5688.

Autosomal genes at a single copy (total copy number 1): 22,879. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
